Somatic mutation profile of tumor specimen 0DODO2 from CCDI case PBCCEK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 11.9 years (4,362 days).
Specimen 0DODO2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e665980-23df-4dac-8d0f-a906d7b16902.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DODMA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a80e9e8c-c758-4900-b66a-2e5c385ee652

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTC34 | c.2191C>T p.R731W | Missense Mutation (SNP) | VAF 82/237 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs551740211; called by muse, mutect2, varscan2
- ITM2A | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.153); called by muse, mutect2
- XRCC5 | c.866T>C p.I289T | Missense Mutation (SNP) | VAF 9/250 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2
- CTAGE1 | c.300C>A p.T100= | Silent (SNP) | VAF 12/342 reads (4%) | called by muse, mutect2
- DNAH1 | c.5556G>A p.T1852= | Silent (SNP) | VAF 53/534 reads (10%) | catalogued as rs769074017; called by muse, mutect2
- NPRL2 | c.*41C>G | 3'UTR (SNP) | VAF 14/163 reads (9%) | called by muse, mutect2
